CCDI case PBCMLK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8d0b84a1-5246-4344-a250-bdbed30edfaa

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 13.6 years (4,960 days).

Biospecimens (3 samples)
- Sample 0DVCDX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVCF7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DVCFW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
